Somatic mutation profile of tumor specimen TCGA-F9-A7VF-01A (aliquot TCGA-F9-A7VF-01A-11D-A33Q-10) from TCGA case TCGA-F9-A7VF, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.1 years (27,446 days).
Specimen TCGA-F9-A7VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ffd5bc0-0a41-473f-8d08-9326c48add08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F9-A7VF-10A (Blood Derived Normal), aliquot TCGA-F9-A7VF-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9efae9e7-a25e-4f62-b9d8-fc2721617017

The open-access MAF lists 80 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 19, Frame Shift Del 5, Nonsense Mutation 4, Intron 3, Frame Shift Ins 2, Splice Site 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100156120; called by muse, mutect2, varscan2
- AMIGO1 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100880952; called by muse, mutect2, varscan2
- ATG7 | c.875T>A p.M292K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100606572; called by muse, mutect2, varscan2
- BCAS1 | c.773A>C p.D258A | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101005999; called by muse, mutect2, varscan2
- CCDC150 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.077); catalogued as COSV99776412; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs756981126, COSV100575012; called by muse, mutect2, varscan2
- CFAP46 | c.7114A>C p.T2372P | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99583810; called by muse, mutect2, varscan2
- CFAP69 | c.880A>T p.K294* | Nonsense Mutation (SNP) | VAF 136/259 reads (53%) | catalogued as rs750199884, COSV60187482; called by muse, mutect2, varscan2
- DDX20 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs767839185, COSV100865874; called by muse, mutect2, varscan2
- DDX5 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as rs781979552, COSV56747998; called by muse, mutect2, varscan2
- EBF3 | c.423C>G p.Y141* | Nonsense Mutation (SNP) | VAF 42/86 reads (49%) | catalogued as COSV100798974; called by muse, mutect2, varscan2
- ERCC2 | c.1808A>C p.K603T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs745695024, COSV101228782; called by muse, mutect2, varscan2
- EXOC7 | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1362541920, COSV100134771; called by muse, mutect2, varscan2
- EXOC7 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100134775; called by muse, mutect2, varscan2
- F12 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV99499373; called by muse, mutect2, varscan2
- F5 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894933282, COSV100888844; called by muse, mutect2, varscan2
- FAM43A | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100316339; called by muse, mutect2, varscan2
- FLG | c.2464C>A p.H822N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64241080; called by muse, mutect2, varscan2
- GDA | c.578+2T>A p.X193_splice | Splice Site (SNP) | VAF 42/99 reads (42%) | catalogued as COSV99428711; called by muse, mutect2, varscan2
- HAS3 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99544092; called by muse, mutect2, varscan2
- HERC2 | c.12189G>C p.W4063C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99870407; called by muse, mutect2, varscan2
- HS3ST1 | c.160T>A p.L54M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99136650; called by muse, mutect2, varscan2
- IGFL3 | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV100407813; called by muse, mutect2, varscan2
- IGFL3 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV100407814; called by muse, mutect2, varscan2
- IL17RC | c.719G>A p.S240N (on ENST00000295981 / NM_153461.4; = p.S169N on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99924633; called by muse, mutect2, varscan2
- IL4R | c.2368A>G p.K790E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99404625; called by muse, mutect2, varscan2
- ITPR3 | c.2269G>T p.V757L | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs1478853929, COSV100966846, COSV65407234; called by muse, mutect2, varscan2
- LACTB | c.442G>T p.V148F | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99978796; called by muse, mutect2, varscan2
- MAEA | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99295097; called by muse, mutect2, varscan2
- MAVS | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 138/241 reads (57%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.677); catalogued as COSV100816227; called by muse, mutect2, varscan2
- MYH7 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV100805627; called by muse, mutect2, varscan2
- PCSK5 | c.910G>C p.G304R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100949395, COSV65089207; called by muse, mutect2, varscan2
- PCSK5 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949396; called by muse, mutect2, varscan2
- PKD2L2 | c.1755C>G p.Y585* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99220900; called by muse, mutect2, varscan2
- PLEC | c.13545G>T p.W4515C (on ENST00000322810 / NM_201380.4; = p.W4405C on NM_000445.5) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100509754; called by muse, mutect2
- PPID | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | catalogued as COSV100306683; called by muse, mutect2, varscan2
- PRKAR1A | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV100675046; called by muse, mutect2, varscan2
- PRRC2B | c.75T>A p.D25E | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100621357; called by muse, mutect2, varscan2
- RFX5 | c.332A>T p.Q111L | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100923809; called by muse, mutect2, varscan2
- SCG2 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1184442650, COSV100544578; called by muse, mutect2, varscan2
- SLC13A3 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs774974721, COSV51720256; called by muse, mutect2, varscan2
- SLC6A4 | c.1616T>A p.I539N | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99911164; called by muse, mutect2, varscan2
- TRAP1 | c.704+1G>C p.X235_splice | Splice Site (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99892993; called by muse, mutect2, varscan2
- TRIM56 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60157335; called by muse, mutect2, varscan2
- TRPV1 | c.1685T>C p.M562T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV99438609; called by muse, mutect2, varscan2
- TTN | c.52777G>A p.V17593M (on ENST00000591111; = p.V10169M on NM_003319.4) | Missense Mutation (SNP) | VAF 61/159 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV100591831; called by muse, mutect2, varscan2
- VEGFD | c.986A>C p.K329T | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as COSV99938239; called by muse, mutect2, varscan2
- XIRP2 | c.7037C>T p.S2346F (on ENST00000628543; = p.S2521F on NM_152381.6) | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs777033757, COSV54691839, COSV54731131; called by muse, mutect2, varscan2
- ABCC9 | c.4304_4305del p.P1435Rfs*9 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- DVL3 | c.2012dup p.P672Afs*39 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by pindel, varscan2
- LAMP2 | c.1220_1221dup p.E408Mfs*28 | Frame Shift Ins (INS) | VAF 125/208 reads (60%) | called by mutect2, pindel, varscan2
- MID1 | c.516del p.L173* | Frame Shift Del (DEL) | VAF 40/75 reads (53%) | called by mutect2, pindel, varscan2
- PITPNB | c.784T>A p.S262T | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB1 | c.5915del p.P1972Lfs*18 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- STAT5B | c.1299_1306del p.E433Dfs*10 | Frame Shift Del (DEL) | VAF 88/180 reads (49%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.6024del p.A2009Lfs*9 | Frame Shift Del (DEL) | VAF 50/106 reads (47%) | called by mutect2, pindel, varscan2
- ACTB | c.846C>T p.I282= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV59320797; called by muse, mutect2, varscan2
- CALM1 | c.333A>C p.T111= | Silent (SNP) | VAF 91/188 reads (48%) | catalogued as COSV100811126; called by muse, mutect2, varscan2
- CHRM2 | c.516G>A p.E172= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV57765010, COSV57773638, COSV57786807; called by muse, mutect2, varscan2
- COQ2 | c.1221G>A p.K407= | Silent (SNP) | VAF 69/196 reads (35%) | catalogued as COSV100269868; called by muse, mutect2, varscan2
- FBXL15 | c.282G>C p.L94= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99192129; called by muse, mutect2, varscan2
- GRAMD1C | c.1881C>G p.L627= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs760280777, COSV100822730; called by muse, mutect2, varscan2
- HEATR5A | c.5271C>T p.Y1757= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV101119513; called by muse, mutect2, varscan2
- HIVEP3 | c.6414C>A p.A2138= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV56022016, COSV99911268; called by muse, mutect2, varscan2
- HSPG2 | c.6342A>G p.E2114= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV101020339; called by muse, mutect2, varscan2
- MYCBP2 | c.6534T>C p.H2178= (on ENST00000357337; = p.H2216= on NM_015057.5) | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100629029; called by muse, mutect2, varscan2
- OR5T2 | c.459C>T p.L153= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV100506783; called by muse, mutect2, varscan2
- RBM15B | c.2241C>A p.I747= | Silent (SNP) | VAF 71/119 reads (60%) | catalogued as COSV100081872; called by muse, mutect2, varscan2
- RNF111 | c.1275T>A p.T425= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100788685; called by muse, mutect2, varscan2
- RPS3A | c.618T>C p.P206= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV99923587; called by muse, mutect2, varscan2
- SH3TC1 | c.2058C>T p.P686= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99794319; called by muse, mutect2, varscan2
- SIGIRR | c.684T>C p.L228= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1403644286, COSV100229765; called by muse, mutect2, varscan2
- SLC14A2 | c.372A>G p.R124= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV99674930; called by muse, mutect2, varscan2
- ZNF875 | c.1029C>T p.N343= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100183004; called by muse, mutect2, varscan2
- ZSWIM5 | c.2658G>A p.E886= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV99869826; called by muse, mutect2, varscan2
- FAM86C1P | n.376C>A | RNA (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100660571; called by muse, mutect2, varscan2
- MPIG6B | c.621+28A>G | Intron (SNP) | VAF 62/72 reads (86%) | catalogued as COSV101008016; called by muse, mutect2, varscan2
- SHC1 | c.1624-300G>C | Intron (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- VAT1 | c.-2C>A | 5'UTR (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100849666; called by muse, mutect2, varscan2
- VPS50 | c.942+25C>T | Intron (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99297717; called by muse, mutect2, varscan2
